Gene-level copy-number profile of tumor specimen TCGA-CV-7095-01A from TCGA case TCGA-CV-7095, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 87.7 years (32,022 days).
Specimen TCGA-CV-7095-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.4d11b422-c1b6-4c71-9078-59cfbd0178c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7095-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1479f8c1-7606-4ff9-9f84-8cb4b7b6d669

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,696; copy number 2: 37,898; copy number 3: 12,592; copy number 4: 1,588; copy number 5: 620; copy number 6: 190; copy number 7: 3; copy number 8: 169; copy number 10: 43; copy number 14: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7095-01A-21D-2010-01): tumor purity 0.56, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,038 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:156,305,108–157,876,330, 17 genes, copy number 5 (within-gene range 3–5): AC074099.1, NR4A2, GPD2, LINC01958, RPLP0P7, AC096589.2, AC096589.1, AC108057.1, CDK7P1, GALNT5, RN7SKP281, ERMN, FAM133DP, CYTIP, ACVR1C, AC019186.1, ACVR1.
- chr2:168,451,324–205,798,133, 603 genes, copy number 5 (broad region; genes not listed).
- chr7:54,721,724–56,229,782, 49 genes, copy number 8: AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, AC006970.2, CCNJP1.
- chr8:35,235,475–35,796,550, 1 gene, copy number 6 (within-gene range 1–6): UNC5D.
- chr8:35,525,176–39,417,378, 88 genes, copy number 6 (broad region; genes not listed).
- chr8:80,967,810–81,112,068, 3 genes, copy number 7 (within-gene range 3–7): PAG1, AC022778.1, AC079209.2.
- chr11:66,744,451–66,843,516, 1 gene, copy number 8 (within-gene range 3–8): C11orf80.
- chr11:66,842,835–71,818,238, 175 genes, copy number 8–14 (within-gene range 1–14) (broad region; genes not listed).
- chr19:51,198,855–52,564,464, 100 genes, copy number 6 (broad region; genes not listed).
- chr19:52,564,076–52,564,231, 1 gene, copy number 6: RPL39P34.

Autosomal genes at a single copy (total copy number 1): 4,989. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
